Surgical pathology report (de-identified scan), TCGA case TCGA-ZP-A9CZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-ZP-A9CZ-01A (Primary Tumor).

[page 1 of 3]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

Component
SURG PATH FINAL REPORT

ICD O-3
Carcinoma, hepatocellular NOS 8170/3
Site: Liver C22.0
W 3/3/14

Accession #:

Specimen:
Date of Procedure:
Performing Physician:

A. Hypervascular liver lesion segment 6

Clinical Notes:

Liver mass. Cirrhosis. Rule out malignancy. Hep B
carrier. Fresh tissue sent to tissue bank.

Diagnosis:

- A. Liver, segment 6, excision:
- Well-differentiated hepatocellular carcinoma (2.0 cm).
- Surrounding liver with bridging fibrosis (stage 3).
- AJCC Stage: pT1 pNX pMX.
- Please see Tumor Characteristics.

NOTE: The previous case was reviewed in conjunction with this case.

(Electronically signed by)
Verified:

Tumor Characteristics:

A: Liver, Resection (AJCC 7th Ed., 2010)

MACROSCOPIC

SPECIMEN TYPE:

Segmentectomy (segment 6)

FOCALITY:

Solitary (specify location): Segment 6

TUMOR SIZE:

Greatest dimension: 2.0 cm

Additional dimensions: 1.5 x 1.5 cm

MICROSCOPIC

HISTOLOGIC TYPE:

[page 2 of 3]
[REDACTED]

Hepatocellular carcinoma
HISTOLOGIC GRADE:
GI: Well differentiated
PRIMARY TUMOR (pT):
pT1: Solitary tumor without vascular invasion
REGIONAL LYMPH NODES (pN):
pNX: Regional lymph nodes cannot be assessed

Accession #:

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 12
mm

Specify margin: Parenchymal

LYMPH-VASCULAR INVASION:

Macroscopic Venous (Large Vessel) Invasion

Not identified

Microscopic (Small Vessel) Invasion

Not identified

ADDITIONAL PATHOLOGIC FINDINGS:

Bridging fibrosis

COMMENT(S):

DISTANT METASTASIS:

Cannot be assessed

Gross:

A. The specimen is labeled "hypervascular liver lesion segment 6." Received in is a 22 gm, 5.0 x 3.5 x 2.5 cm portion of liver which is received in two pieces. The capsule is purple-gray and smooth with a 1.5 x 1.5 x 0.5 cm white-gray nodular bulge. The resection surface is marked with black ink. Further sectioning reveals a 2.0 x 1.5 x 1.5 cm well-circumscribed, tan-gray mass corresponding to the capsular bulge. The mass exhibits a nodular, solid, tan cut surface. The mass is 1.2 cm from the closest black-inked resection surface. The mass is well-demarcated from the remaining hepatic parenchyma is tan-brown. A portion of the mass and unremarkable liver is sent to tissue bank. Representative sections are then submitted for permanent as follows:

Cassette Designation:

A1	Mass with closest resection margin
A2-4	Mass with adjacent parenchyma
A5	Unremarkable parenchyma

[page 3 of 3]
Microscopic:

A histological examination has been performed.

A. H and E and trichrome-stained sections show a well-circumscribed nodule composed of hepatocytes with thickened cell plates. A nodular architecture is present in this

Accession #:

area. The neoplastic hepatocytes contain increased NC ratio and pleomorphic nuclei. A reticulin stain demonstrates loss and paucity of the reticulin network. The surrounding liver parenchyma demonstrates portal tracts with bridging fibrosis.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time	Lab Status	Entered by
	In process	

Criteria	hw 12/11/13	Yes	No

Source: NCI Genomic Data Commons file d7f25b4d-a3b4-4684-b1f5-62706ef3e0c4 (TCGA-ZP-A9CZ.C3F4669C-9E5D-4A46-84A8-E78BF2D5EA92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).